Surgical pathology report (de-identified scan), TCGA case TCGA-IW-A3M5, project TCGA-SARC (Sarcoma), tissue source site Cedars Sinai, specimen TCGA-IW-A3M5-01A (Primary Tumor).

[page 1 of 5]
Pathologist: I
Assistant:
Date of Procedure:
Date Received

Ordering M.D.:
Copies To:

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1 Additional sections or studies

DIAGNOSIS:

A. UTERUS, CERVIX, BILATERAL TUBES, AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY:

- Myometrium and serosa:
- Leiomyosarcoma, high grade, gynecologic type (See comment)
- Size: 5.5 cm in greatest dimension
- Angiolymphatic invasion: Present, extensive, at serosal margin
- Mitotic index: >20/10 HPF
- Tumor cell necrosis: Present, <10%
- AJCC Pathologic Stage (2010, 7th Ed): pT1b/N0
- Endometrium:
- Ulcerated, focally by leiomyosarcoma
- Atrophy and biopsy site changes
- Cervix:
- Chronic and focal acute cervicitis with atrophy
- No malignancy identified
- Right and left parametria:
- No significant pathologic alteration
- Right ovary:
- Atrophic changes
- No malignancy identified
- Left ovary:
- Atrophic changes
- No malignancy identified
- Right fallopian tube:
- No significant pathologic alteration
- Left fallopian tube:
- No significant pathologic alteration

1CD-0-3

leiomyosarcoma, NOS 8890/3
Site: uterus, NOS C55.9

hw
12/20/11

B. LEFT PELVIC LYMPH NODES, DISSECTION:

- Three lymph nodes with dystrophic calcifications and no malignancy identified (0/3)

C. RIGHT PARAAORTIC LYMPH NODES, DISSECTION:

- Four lymph nodes with no malignancy identified (0/4)

D. LEFT PARAAORTIC LYMPH NODE, EXCISION:

- Mature adipose and fibrovascular tissue, nerves and ganglion cells
- No lymphoid tissue identified

[page 2 of 5]
***** Addendum - Please See End of Report *****

1CD-0-3
leiomyosarcoma, NOS
8890/3

E., F. OMENTUM #1 AND 2, OMENTECTOMY:

- Mature adipose tissue with no malignancy identified
- One lymph node with no malignancy identified (0/1)

Site: uterus, NOS C55-9

AW
12/20/11

COMMENT: The keratin positivity noted in the prior biopsy is entirely consistent with leiomyosarcoma. Although some foci (A15) showed cells which resemble rhabdomyoblasts, MyoD1 is negative. No glandular component is identified in the resection specimen and no keratin positivity is identified in a section stained from this case, which argue against a malignant mixed mullerian tumor. The findings were relayed to Dr. by campus email.

HISTORY:

Uterine cancer.

MICROSCOPIC FINDINGS:

See diagnosis.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
Desmin	A16	Positive, strongly and diffusely
S-100	A16	Focally positive
Actin, smooth muscle	A16	Positive
MyoD1	A16	Negative (cytoplasmic reactivity)
Keratin (AE1/AE3)	A16	Negative

*These IHC studies were interpreted in conjunction with appropriate positive and negative controls which demonstrated the expected positive and negative reactivity.

GROSS:

A. UTERUS, BILATERAL TUBES, OVARIES AND CERVIX

Labeled with the patient's name, labeled "uterus, bilateral tubes, ovaries and cervix", received fresh for intraoperative gross consultation, and subsequently fixed in formalin is a 190 gram total hysterectomy and bilateral salpingo-oophorectomy specimen. The uterus is about 7.5 x 6.0 x 6.0 cm. The cervical portion of the uterus is 2.5 x 2.5 x 2.2 cm. The endometrial cavity is about 4.0 cm wide and about 4.0 cm in length. The endometrial lining is 0.1 cm. The muscular uterine wall ranges from 1.2 to 2.0 cm in maximum thickness. There are parametrial tissues attached to the uterus. Those on the right are about 2.5 x 1.5 x 1.0 cm and those on the left are about 2.5 x 1.2 x 0.8 cm. The right ovary is 1.5 x 1.0 x 0.6 cm. A 1.3 x 0.7 x 0.2 cm portion of right ovary appears to have been previously removed for research purposes. The right fallopian tube is 4.5 cm in length and 0.3-0.5 cm in diameter. The lumen is 0.1 cm. The left ovary is 1.5 x 1.0 x 0.5 cm. The left fallopian tube is 4.5 cm in length and 0.4-0.6 cm in diameter. The lumen is 0.1 cm.

There is a soft, tan, friable, hemorrhagic, pedunculated 5.5 x 5.0 x 3.5 cm endometrial tumor that largely replaces the uterine fundus, corpus, and lower uterine segment. The tumor invades greater than 95% of the myometrial wall in the lower uterine segment (grossly 2.0 cm into a 2.0 cm myometrial wall). The tumor abuts the serosa of the anterior and posterior lower uterine segment but does not grossly extend through the serosa. The tumor does not grossly extend into the ectocervix or parametrial soft tissues. A 1.0 x 0.7 x 0.3 cm nodule is present in the posterior endocervical wall, possibly representing tumor versus post-fixation artifact. The endocervical canal is otherwise uninvolved by tumor. No metastatic tumor is identified in the adnexa.

Ink key: anterior uterine serosa - yellow; posterior uterine serosa - black.

[page 3 of 5]
***** Addendum - Please See End of Report *****

Gross photographs are obtained.

Representative sections are submitted.

Slide key:

- A1. Right ovary - 1
- A2. Right fallopian tube and fimbria - 4
- A3. Left ovary - 1
- A4. Left fallopian tube and fimbria - 4
- A5, A6. Right parametria - 2, 3
- A7-A9. Left parametria - 2 each
- A10. Anterior cervix - 2
- A11. Posterior cervix - 2
- A12. Posterior cervix with possible tumor nodule versus post-fixation artifact - 2
- A13. Inferior-most aspect of anterior lower uterine segment grossly negative for tumor - 1
- A14. Inferior -most aspect of anterior lower uterine segment grossly negative for tumor - 1
- A15, A16. Anterior lower uterine segment with closest relationship of tumor to serosa - 1 each
- A17-A19. Posterior lower uterine segment with closest relationship of tumor to serosa - 1 each
- A20, A21. Contiguous section of tumor in uterine body - 1 each
- A22. Non-neoplastic anterior endometrium adjacent to tumor - 1
- A23. Non-neoplastic posterior endometrium adjacent to tumor - 1

B. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "left pelvic lymph node", and received in formalin is a 1.8 x 1.6 x 0.5 cm aggregate of fibroadipose tissue. A 0.5 x 0.5 x 0.3 cm lymph node is identified.

No gross tumor is identified within the lymph node.

Entirely submitted.

Slide key:

- B1. One lymph node, bisected - 2
- B2, B3. Remainder of tissue - 1, 2

C. RT PARAAORTIC LYMPH NODE

Labeled with the patient's name, labeled "Rt. para-aortic lymph node", and received in formalin is a 1.5 x 0.8 x 0.5 cm aggregate of fibroadipose tissue. Four possible lymph nodes ranging from 0.5 to 1.2 cm in greatest dimension are identified.

No gross tumor is identified within the lymph nodes.

Entirely submitted.

Slide key:

- C1. Four possible lymph nodes - 4
- C2, C3. Remainder of tissue - 5, 2

D. LT. PARAAORTIC LYMPH NODE

Labeled with the patient's name, labeled "Lt. paraaortic lymph node", and received in formalin is a 1.5 x 1.0 x 0.4 cm fragment of tan-brown soft tissue.

No lymph node or tumor is identified.

[page 4 of 5]
***** Addendum - Please See End of Report *****

Entirely submitted.

Slide key:

D1. 1

E. OMENTUM #1

Labeled with the patient's name, labeled "omentum #1", and received in formalin is a 5.0 x 3.5 x 0.8 cm partial omentectomy specimen.

No gross tumor is identified.

Representative sections.

E1-E3. 1 each

F. OMENTUM #2

Labeled with the patient's name, labeled "omentum #2", and received in formalin is a 6.0 x 2.8 x 0.8 cm partial omentectomy specimen.

No gross tumor is identified.

Representative sections.

Slide key:

F1-F3. 1 each

Gross dictated by

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

A. (GROSS EXAMINATION):

- Large intrauterine tumor with focal extension to serosal surface
- Tissue taken for research purposes

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

ADDENDUM,

This addendum is issued following a request for additional immunostains (CD10, ER, PR, by the reviewing pathologist at These are performed in a second panel listed with the results below:

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
Estrogen Receptor QL	A16	Negative
HMB45	A16	Negative

SURGICAL PATHOLOGY REPORT

[page 5 of 5]
***** - Please See End of Report *****

Progesterone Receptor QL	A16	Negative
CD10	A16	Negative
Melan A	A16	Negative
Caldesmon	A16	Negative

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Page 5 of 5

Source: NCI Genomic Data Commons file 36aaf051-11b3-4f9c-a63a-fd534b8f3712 (TCGA-IW-A3M5.CE168591-ED09-49A8-B501-BF91688C62C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).